Gene-level copy-number profile of tumor specimen TCGA-AN-A0FF-01A from TCGA case TCGA-AN-A0FF, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 32.7 years (11,929 days).
Specimen TCGA-AN-A0FF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.9add77c5-e24a-4c2f-9e79-fa09dc8697cd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0FF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d5a2a5e6-029c-4b37-9749-91479938f28b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 3,767; copy number 2: 50,025; copy number 3: 3,389; copy number 4: 1,580; copy number 5: 1,026.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0FF-01A-11D-A036-01): tumor purity 0.74, ploidy 2.08, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,228,300–167,826,812, 16 genes: HPAT5, AL353747.3, AL353747.2, UNC93A, TTLL2, AL021331.1, TCP10L3, AL356123.1, LINC02538, AL356123.2, LINC02487, AL009178.1, LINC01558, AL009178.2, AL009178.3, AFDN-DT.
- chr6:169,286,534–169,810,102, 17 genes: BX322234.2, VTA1P1, LINC02519, AL009176.1, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,026 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,225,779–214,357,615, 430 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:225,486,835–248,919,946, 594 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:75,020,969–75,209,839, 2 genes, copy number 5: AC073525.1, KCNC2.

Autosomal genes at a single copy (total copy number 1): 3,767. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
